Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A9FP, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A9FP-01A (Primary Tumor).

[page 1 of 4]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-O-3
Carcinoma, squamous cell
NOS 8070/3
Site: Esophagus, middle
thick C15.4
J2 4/5/14

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married ☐ Divorced ☐ Widow	DIETARIANESSE	Blood Pressure
☐ Male ☒ Female				Heart Rate

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	Trouble Swallowing
Symptoms:	Weight loss
Clinical Findings:	
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 4]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal	years old	03
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☒ Post-menopausal	years old	01
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:					

[page 3 of 4]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the oesophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: II		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the upper part of oesophagus			
Primary Tumor			
Organ	Detailed Location	Size	
ESOPHAGUS TUMOR	Middle Third	2 x 0.8 x 0.8 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: II			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 4]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			Structural Pattern			Cellular Differentiation			Nuclear Appearance		
	+	-		+	-		+	-		+	-
Diffuse		☒	Streaming			Squamous			Adenomatous		
Mosaic	☒	☒	Storiform			Squamoid Cell	☒		Glandular cell		
Necrosis		☒	Fibrosis			Spindle Cell	☒		Cell Stratification		
Lymphocytic Infiltration	☒		Palisading			Keratin	☒		Secretion		
Vascular Invasion		☒	Cystic Degeneration			Desmosome	☒		Intracyt. Vacuole		
Clusterized	☒	☒	Bleeding			Pearl			Gland formation		
Alveolar Formation		☒	Myxoid Change			Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor					
Indian File		☒	Psammoma/Calcification			Nuclear Appearance					
Nuclear Atypia:			0			I			II		
Aniso Nucleosis									☒		
Hyperchromatism									☒		
Nucleolar Prominent									☒		
Multinucleated Giant Cell									☒		
Mitotic Activity									☒		
Nuclear Grade:									☒		

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma **Grade:** 3

Comments:

Director, Research Pathology

uate

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS

Source: NCI Genomic Data Commons file 07993ea5-8e9f-4f03-af80-b86bd7a27ad2 (TCGA-LN-A9FP.E4974B0B-73AF-4FEC-9E33-3935F4A8E441.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).